TCGA case TCGA-V4-A9EO — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bcb87378-9f43-45e4-bdf2-f6dfa6ac5b8c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 74 years; Year of birth: 1938; Vital status: Dead; Days to death: 1,841 days (5.0 years); Year of death: 2018.

Diagnoses (1)
1. Mixed epithelioid and spindle cell melanoma: ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.40; Tissue or organ of origin: Ciliary body; Site of resection or biopsy: Ciliary body; Classification of tumor: primary; Age at diagnosis: 74.4 years (27,190 days); Year of diagnosis: 2013; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,841 days (5.0 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Consistent pathology review: No; Epithelioid cell percent range: 61-90%; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: 1-30%; Tumor depth measurement: 14; Tumor shape: Mushroom.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 25.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -6 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dacarbazine; Days to treatment start: 1,389 days (3.8 years); Days to treatment end: 1,494 days (4.1 years); Number of cycles: 3; Treatment dose: 800 mg/m2; Treatment outcome: No Response; Reason treatment ended: Other.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 407 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 594 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 773 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,344 days (3.7 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,344 days (3.7 years).
- Days to follow up: 1,841 days (5.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 16.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 172 cm; BMI: 23.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-V4-A9EO-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Choroid.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: 1-30%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 1 loss; Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 773 days; disease-specific survival: no event (censored), 773 days; progression-free interval: no event (censored), 773 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EO-01A-12D-A39V-01): tumor purity 0.98, ploidy 3.36, whole-genome doublings 1.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- days to imaging: 1494
- days to metastasis: 1344
- days to outcome: 1494
- days to pharm therapy imaging 1: 1096
- days to procedure 1: -6
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- drug name 1: deticene
- evaluated by imaging: yes
- icd 10: C69.30
- imaging type: Abdo CT
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- number cycles 1: 3
- outcome: Progressive Disease
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy evaluated by imaging 1: Yes
- pharm therapy imaging type 1: CT
- pharm therapy status 1: treatment discontinued
- pharm therapy status reason 1: Lack of Response
- resection status 1: R0
- staging system: AJCC
- t stage: T4b
- test methodology: aCGH
- test result: high risk
- tissue of origin: choroid
- unresectable 1: no
